TARGET case TARGET-15-SJMPAL043513 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/8d2a39f5-a375-4479-9454-36b9088ebdef

Demographics
Sex at birth: male; Age at index: 10 years.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 10.6 years (3,873 days); Year of diagnosis: 2011.

Follow-up (1 entry)
- First event: Relapse; Timepoint: Follow-up.

Biospecimens (3 samples)
- Samples TARGET-15-SJMPAL043513-04A, TARGET-15-SJMPAL043513-04B (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL043513-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Protocol: AIEOP
- WHO ALAL Classification: B/M
- WHO RL1: B/M
